Somatic mutation profile of tumor specimen TCGA-KS-A41F-01A (aliquot TCGA-KS-A41F-01A-11D-A23M-08) from TCGA case TCGA-KS-A41F, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 37.1 years (13,545 days).
Specimen TCGA-KS-A41F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d113102-f618-4652-8954-7ce2b4207381.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KS-A41F-11A (Solid Tissue Normal), aliquot TCGA-KS-A41F-11A-11D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4d3e808-1429-46f7-87f9-7d1dc1a7f615

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AFMID | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774921922, COSV100014876; called by muse, mutect2
- BCL9 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99324759; called by muse, mutect2
- FARP1 | c.714del p.K239Rfs*12 | Frame Shift Del (DEL) | VAF 7/85 reads (8%) | catalogued as COSV60344847; called by mutect2, pindel
- GPRIN2 | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV100966334; called by muse, mutect2, varscan2
- LRRC14 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.668); catalogued as COSV52880768, COSV99467273; called by muse, mutect2, varscan2
- REG3A | c.151T>A p.C51S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs772275781, COSV100532594; called by muse, mutect2, varscan2
- SYNE1 | c.14228C>T p.T4743I (on ENST00000367255 / NM_182961.4; = p.T4672I on NM_033071.3) | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.226); catalogued as COSV99557638, COSV99572729; called by muse, mutect2
- AP4M1 | c.1020G>A p.V340= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100384800; called by muse, mutect2, varscan2
